Surgical pathology report (de-identified scan), TCGA case TCGA-IN-8462, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-8462-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: GALLBLADDER, CHOLECYSTECTOMY –
BENIGN GALLBLADDER WITH CHOLESTEROLS

PART 2: OMENTUM, EXCISION –

BENIGN FIBROADIPOSE TISSUE.

PART 3: LYMPH NODE, LEVEL 8, DISSECTION –
TWO (2) BENIGN LYMPH NODES.

PART 4: LYMPH NODE, LEVEL 9, BIOPSY –
ONE (1) BENIGN LYMPH NODE.

PART 5: ESOPHAGUS, ESOPHAGECTOMY –

- A. INVASIVE MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA, MEASURING 5.3 CM, INVOLVING GASTROESOPHAGEAL JUNCTION.
- B. TUMOR INVADES INTO MUSCULARIS PROPRIA.
- C. ALL SURGICAL MARGINS, INCLUDING PROXIMAL ESOPHAGEAL, DISTAL GASTRIC, AND CIRCUMFERENTIAL (RADIAL) MARGINS ARE FREE OF TUMOR.
- D. NO DEFINITE LYMPHOVASCULAR SPACE INVASION SEEN.
- E. PERINEURAL INVASION SEEN.
- F. METASTATIC ADENOCARCINOMA INVOLVING TWO (2) OF SIX (6) LYMPH NODES (2/6).
- G. AJCC PATHOLOGIC TUMOR STAGE: pT2 N1

PART 6: PROXIMAL MARGIN, EXCISION –

BENIGN ESOPHAGEAL TISSUE WITH CHRONIC INFLAMMATION.

PART 7: ANASTOMOSIS, EXCISION –

BENIGN GASTRIC AND ESOPHAGEAL TISSUE WITH MILD CHRONIC INFLAMMATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint centered on esophagogastric junction
TUMOR SIZE: Greatest dimension: 5.3 cm
Additional dimensions: 3.3 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM)
pT2
pN1
Number of lymph nodes examined: 9
Number of lymph nodes involved: 2
pM Not applicable
PRIOR TREATMENT: Treatment history not known
MARGINS
Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
ANGIOLYMPHATIC INVASION: Absent
ADDITIONAL PATHOLOGIC FINDINGS: None identified

HER2 FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

Cells Analyzed: 125

Ratio HER2/CEP17: 1.75

SNR: 3.7

CNR: 2.1

% Hyperdiploid: 25(20.0%)

HER2 IMMUNOPEROXIDASE STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

IHC score: 0.

Source: NCI Genomic Data Commons file a6dc39a8-370d-40cd-9c0b-870b190e7594 (TCGA-IN-8462.18323D21-224B-49C8-94C8-FD8E2EC34A87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).